Somatic mutation profile of tumor specimen 0DODOB from CCDI case PBCCBJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 18.3 years (6,686 days).
Specimen 0DODOB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 754d8859-aa92-4df7-869d-bc47ef51ff38.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DODM9 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90c96654-f5b8-40f5-97d7-55e284836523

The open-access MAF lists 4 somatic variants for this specimen: 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 3, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTBP2 | c.924C>T p.L308= (on ENST00000426398 / NM_001300986.2; = p.L300= on NM_021190.4) | Silent (SNP) | VAF 13/417 reads (3%) | called by muse, mutect2
- SLCO1B1 | c.657T>A p.G219= | Silent (SNP) | VAF 42/1166 reads (4%) | called by muse, mutect2
- SPANXN1 | c.159G>A p.A53= | Silent (SNP) | VAF 36/672 reads (5%) | catalogued as rs782807503, COSV65122958, COSV65123182; called by muse, mutect2
- SHROOM2 | c.2791-13T>A | Intron (SNP) | VAF 14/370 reads (4%) | called by muse, mutect2
